Somatic mutation profile of tumor specimen TCGA-BA-A6DE-01A (aliquot TCGA-BA-A6DE-01A-22D-A31L-08) from TCGA case TCGA-BA-A6DE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.8 years (25,874 days).
Specimen TCGA-BA-A6DE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 023bc468-50cc-44e9-b01e-a4e429116b7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DE-10A (Blood Derived Normal), aliquot TCGA-BA-A6DE-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e80c5c93-bdfd-4259-b545-53e4ab76dd54

The open-access MAF lists 133 somatic variants for this specimen: 95 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 36, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 31/56 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as COSV100267125; called by muse, mutect2, varscan2
- ACP7 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100488662; called by muse, mutect2, varscan2
- ADAM2 | c.1668A>C p.Q556H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV99698058; called by muse, mutect2, varscan2
- ADAMTS13 | c.3302G>A p.G1101E | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV52469833; called by muse, mutect2, varscan2
- ADCY1 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99813140; called by muse, mutect2, varscan2
- AHNAK | c.4504C>A p.H1502N | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV99950209; called by muse, mutect2, varscan2
- ANKRD42 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764888146, COSV52618213; called by muse, mutect2, varscan2
- ANKRD45 | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100322747; called by muse, mutect2, varscan2
- ASB3 | c.1466C>A p.P489Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99712663; called by muse, mutect2, varscan2
- ASB3 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.41); catalogued as COSV99712666; called by muse, varscan2
- ASIC3 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99875229; called by muse, mutect2, varscan2
- BMP2K | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV100622075; called by muse, mutect2, varscan2
- CASR | c.2146A>G p.K716E (on ENST00000490131; = p.K793E on NM_000388.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99949618; called by muse, mutect2, varscan2
- CCDC102B | c.1281A>T p.Q427H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100105314, COSV60148704; called by muse, mutect2, varscan2
- CCDC73 | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs201737265, COSV58797792; called by muse, mutect2, varscan2
- CCNB1IP1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs1438985746, COSV100738518; called by muse, mutect2, varscan2
- CD40 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100953892; called by muse, mutect2, varscan2
- CDH3 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV99869440; called by muse, mutect2, varscan2
- COL22A1 | c.4396C>T p.R1466W | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779417247, COSV57328204; called by muse, mutect2, varscan2
- COL22A1 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs907972324, COSV100280892; called by muse, mutect2, varscan2
- DAB1 | c.1420G>A p.E474K (on ENST00000371231; = p.E441K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.65); catalogued as COSV100976752; called by muse, mutect2, varscan2
- DNAJC21 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs758392850, COSV57759474; called by muse, mutect2, varscan2
- DPYD | c.2273A>G p.K758R | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100929670; called by muse, mutect2, varscan2
- DRC1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs1271834382, COSV99985717; called by muse, mutect2, varscan2
- DST | c.11587C>G p.Q3863E (on ENST00000361203 / NM_001374722.1; = p.Q1451E on NM_015548.5) | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1400251833, COSV55039745, COSV55053992; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99709345; called by muse, mutect2, varscan2
- EIF4G3 | c.659A>T p.E220V | Missense Mutation (SNP) | VAF 81/152 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99946027; called by muse, mutect2, varscan2
- ENTPD5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs761661105, COSV58221517; called by muse, mutect2, varscan2
- FCSK | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV55368670, COSV99851368; called by muse, mutect2
- FSHR | c.923G>T p.R308M | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV100438371; called by muse, mutect2, varscan2
- GLI2 | c.1276G>T p.D426Y (on ENST00000361492 / NM_001374353.1; = p.D443Y on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100084644; called by muse, mutect2, varscan2
- GLRA1 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs1468001309, COSV51015581, COSV99199739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR3A | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.259); catalogued as COSV55468693, COSV55472637; called by muse, mutect2, varscan2
- IBTK | c.2849A>G p.Y950C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100091672; called by muse, mutect2, varscan2
- ICE1 | c.6208C>G p.L2070V | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56827896, COSV99666054; called by muse, mutect2, varscan2
- IGSF10 | c.5094C>A p.S1698R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV99204772; called by muse, mutect2, varscan2
- IL17A | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391719; called by muse, mutect2, varscan2
- INF2 | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99384614; called by muse, mutect2, varscan2
- INVS | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV99318464; called by muse, mutect2, varscan2
- IQCB1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100182205; called by muse, mutect2, varscan2
- KCNK2 | c.694T>C p.F232L (on ENST00000444842 / NM_001017425.3; = p.F217L on NM_014217.4) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV101222397; called by muse, mutect2, varscan2
- KLHL1 | c.907C>A p.H303N | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100918406; called by muse, mutect2, varscan2
- KNG1 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 98/152 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99405997; called by muse, mutect2, varscan2
- LYSMD3 | c.782C>A p.S261* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100270574, COSV60058032; called by muse, mutect2, varscan2
- MAGEC3 | c.1400T>G p.L467R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53581041, COSV68924122; called by muse, mutect2, varscan2
- MATN4 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | PolyPhen probably damaging (0.992); catalogued as rs1360940554; called by muse, mutect2
- MOCS1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs1318933448, COSV51304921; called by muse, mutect2, varscan2
- MTG2 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895212; called by muse, mutect2, varscan2
- MUC17 | c.4286C>G p.T1429S | Missense Mutation (SNP) | VAF 62/818 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100075622; called by muse, mutect2
- MUC17 | c.12292C>A p.P4098T | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100075626; called by muse, mutect2
- MYO15A | c.9880C>T p.R3294W | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377125285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5A | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100698298; called by muse, mutect2, varscan2
- MYO5B | c.2799G>T p.K933N | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV99546667; called by muse, mutect2, varscan2
- NCAPH | c.1445T>C p.V482A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99546325; called by muse, mutect2, varscan2
- NKD1 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99194157; called by muse, mutect2, varscan2
- NOC4L | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100400293; called by muse, mutect2
- NSD1 | c.4723G>T p.E1575* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100729944; called by muse, mutect2, varscan2
- NUP107 | c.2638A>G p.M880V | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs747127320, COSV99972163; called by muse, mutect2, varscan2
- OBSCN | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV99486223; called by muse, mutect2, varscan2
- OBSCN | c.5386G>C p.E1796Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.783); catalogued as rs983090550, COSV99486226; called by muse, mutect2, varscan2
- OSBPL9 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs371808604, COSV61870027; called by muse, mutect2
- PAPPA2 | c.4360G>T p.D1454Y | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100867717; called by muse, mutect2, varscan2
- PHF21A | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57655767, COSV99139747; called by muse, mutect2
- PKD1L2 | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100450483; called by muse, mutect2, varscan2
- PLXNA3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1569554045, COSV100860316; called by muse, mutect2, varscan2
- PTH | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99961739; called by muse, mutect2, varscan2
- RASGRP3 | c.1581C>G p.D527E (on ENST00000402538 / NM_001349975.2; = p.D526E on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV101274944; called by mutect2, varscan2
- SERPINB1 | c.539C>G p.T180R | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101058510, COSV66313875; called by muse, mutect2, varscan2
- SH3RF2 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as rs376569546; called by muse, mutect2, varscan2
- SLC17A3 | c.1067G>C p.R356T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV100399455; called by muse, mutect2, varscan2
- SLC22A25 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV100124127, COSV60594394; called by muse, mutect2, varscan2
- SLC45A1 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99239836; called by muse, mutect2, varscan2
- SLCO2B1 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1351808451, COSV99215345; called by muse, mutect2, varscan2
- SRMS | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99421298, COSV99421763; called by muse, mutect2, varscan2
- STIM1 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | catalogued as COSV100330922, COSV100331132, COSV56154202; called by muse, mutect2, varscan2
- SUPT3H | c.856G>A p.E286K (on ENST00000371460 / NM_181356.3; = p.E275K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs746933715, COSV100178595, COSV60937054; called by muse, mutect2, varscan2
- TET1 | c.4914+2T>C p.X1638_splice | Splice Site (SNP) | VAF 9/18 reads (50%) | catalogued as COSV101019088, COSV65383892; called by muse, mutect2, varscan2
- TM6SF1 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV99362507, COSV99362944; called by muse, mutect2, varscan2
- TMEM87B | c.1487C>G p.S496C | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1456003353, COSV99314774; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs747644318, COSV54871298, COSV99621730; called by muse, mutect2, varscan2
- TRIM13 | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 92/139 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs765041348, COSV100078619; called by muse, mutect2, varscan2
- WFDC3 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV99714902; called by muse, mutect2
- ZMAT1 | c.634A>T p.N212Y | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.331); catalogued as COSV100858982; called by muse, mutect2, varscan2
- ZNF136 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.757); catalogued as rs370384772; called by muse, mutect2, varscan2
- ZNF195 | c.1462C>G p.H488D (on ENST00000399602 / NM_001130520.3; = p.H416D on NM_007152.5) | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99138572; called by muse, mutect2, varscan2
- ZNF507 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100322213; called by muse, mutect2, varscan2
- ZNF664 | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV100544634; called by muse, mutect2, varscan2
- ARID4A | c.1705_1708del p.D569Wfs*5 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- CDH17 | c.62_63del p.Y21Wfs*7 | Frame Shift Del (DEL) | VAF 38/86 reads (44%) | called by pindel, varscan2
- DCAF1 | c.1001T>C p.L334S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KDM6A | c.1631del p.Q544Rfs*4 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.5824_5828del p.D1942Rfs*51 | Frame Shift Del (DEL) | VAF 191/340 reads (56%) | called by mutect2, pindel, varscan2
- PXT1 | c.301-2del p.X101_splice | Splice Site (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- SHFL | c.644-7_654del p.X215_splice | Splice Site (DEL) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- ALMS1 | c.8103A>G p.Q2701= | Silent (SNP) | VAF 60/197 reads (30%) | catalogued as COSV100044163; called by muse, mutect2, varscan2
- ASPH | c.2007C>T p.I669= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV101064612; called by muse, mutect2, varscan2
- BSDC1 | c.1065G>A p.E355= | Silent (SNP) | VAF 55/243 reads (23%) | catalogued as COSV61981773; called by muse, mutect2, varscan2
- C12orf50 | c.987G>A p.A329= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs762685869, COSV100072284, COSV53894688; called by muse, mutect2, varscan2
- CD1E | c.18C>T p.L6= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100937097; called by muse, mutect2, varscan2
- CHST11 | c.315C>T p.N105= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs141459164, COSV57996660; called by muse, mutect2, varscan2
- DACT1 | c.1992G>T p.A664= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs765432256, COSV100242187; called by muse, varscan2
- FAM184A | c.2475C>G p.L825= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV58855930, COSV58857521; called by muse, mutect2, varscan2
- GPR35 | c.312C>T p.I104= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100166754; called by muse, mutect2, varscan2
- GRM1 | c.795T>C p.A265= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV99269795; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1719C>T p.F573= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs782274834, COSV99735873; called by muse, mutect2, varscan2
- IL1B | c.270G>C p.L90= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV99642073; called by muse, mutect2, varscan2
- IRGC | c.858G>A p.A286= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs747072003, COSV54986462; called by muse, mutect2, varscan2
- JHY | c.1875C>T p.G625= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99913966; called by muse, mutect2, varscan2
- LBH | c.45G>C p.S15= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV101257758; called by muse, mutect2
- LRRC4C | c.789T>C p.F263= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV99540285; called by muse, mutect2, varscan2
- LY96 | c.252C>A p.T84= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99514794; called by muse, mutect2, varscan2
- MAP3K19 | c.1725G>T p.P575= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV100209496, COSV59643224; called by muse, mutect2, varscan2
- MUC5AC | c.15111C>T p.V5037= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100611647; called by muse, mutect2, varscan2
- NEFM | c.2031A>G p.K677= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99647649; called by muse, mutect2, varscan2
- NID2 | c.513C>T p.R171= | Silent (SNP) | VAF 86/305 reads (28%) | catalogued as COSV53497522; called by muse, mutect2, varscan2
- OLAH | c.399A>T p.V133= (on ENST00000378228 / NM_001039702.3; = p.V186= on NM_018324.3) | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100984930; called by muse, mutect2, varscan2
- PTK7 | c.2487G>A p.V829= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV57848598; called by muse, mutect2, varscan2
- RINT1 | c.288A>T p.S96= | Silent (SNP) | VAF 50/99 reads (51%) | catalogued as COSV99994689; called by muse, mutect2, varscan2
- SCAP | c.87C>A p.I29= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99653389; called by muse, mutect2, varscan2
- SELE | c.84G>A p.T28= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs754550998, COSV60977447; called by muse, mutect2, varscan2
- SLC45A3 | c.124C>T p.L42= | Silent (SNP) | VAF 60/210 reads (29%) | catalogued as COSV100901376; called by muse, mutect2, varscan2
- SMPD3 | c.879C>T p.G293= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99546209; called by muse, mutect2, varscan2
- SNRPB2 | c.303A>G p.K101= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99855926; called by muse, mutect2, varscan2
- SPON2 | c.771C>A p.V257= | Silent (SNP) | VAF 62/262 reads (24%) | catalogued as COSV99335389; called by muse, mutect2, varscan2
- SYNE3 | c.978G>T p.L326= | Silent (SNP) | VAF 55/172 reads (32%) | catalogued as COSV100516685; called by muse, mutect2, varscan2
- UFL1 | c.789G>A p.Q263= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs1486732803, COSV100990159; called by muse, mutect2, varscan2
- UGT2B28 | c.1584A>G p.R528= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV59430798; called by muse, mutect2, varscan2
- ZC3H15 | c.762T>A p.S254= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100552246; called by muse, mutect2, varscan2
- ZDHHC4 | c.318G>T p.L106= | Silent (SNP) | VAF 76/340 reads (22%) | catalogued as COSV100254126; called by muse, mutect2, varscan2
- ZNF292 | c.5625A>G p.K1875= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV100371620; called by muse, mutect2, varscan2
- KCNK7 | c.718+41G>C | Intron (SNP) | VAF 38/95 reads (40%) | catalogued as COSV58421748; called by muse, mutect2, varscan2
- PPP2R3A | c.1996-3741C>G | Intron (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99388498; called by muse, mutect2, varscan2
